Gene-level copy-number profile of tumor specimen TCGA-D7-5579-01A from TCGA case TCGA-D7-5579, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Body of stomach; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 74.4 years (27,175 days).
Specimen TCGA-D7-5579-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.6e86325f-95bd-46b6-b5d6-85f8ff8f4a04.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-D7-5579-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 813 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/8ac375da-e726-43d1-bce9-4b5e81a87d6a

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 52; copy number 1: 2,617; copy number 2: 26,576; copy number 3: 15,850; copy number 4: 5,083; copy number 5: 4,307; copy number 6: 3,517; copy number 7: 806; copy number 8: 235; copy number 9: 378; copy number 10: 110; copy number 11: 38; copy number 12: 16; copy number 13: 14; copy number 14: 10; copy number 15: 18; copy number 16: 12; copy number 17: 62; copy number 20: 45; copy number 23: 41; copy number 24: 1; copy number 28: 22.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-D7-5579-01A-01D-1599-01): tumor purity 0.27, ploidy 2.83, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 52 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:56,099,680–56,233,330, 1 gene (within-gene range 0–4): ANKRD55.
- chr5:56,146,739–60,522,120, 51 genes (within-gene range 0–1): RNA5SP184, C1GALT1P2, RNA5SP185, PSMC1P4, RNU6ATAC2P, AC034245.1, HMGN1P17, LINC01948, AC008391.1, RPL26P19, C5orf67, AC022431.1, AC008940.1, MAP3K1, AC008937.2, AC008937.1, SETD9, MIER3, AC008937.3, AC016644.1, AC114973.1, AC034244.1, AC034244.2, Y_RNA, GPBP1, AC025470.1, AC025470.2, SALL4P1, ACTBL2, LINCR-0003, AC008780.1, AC106822.1, LINC02225, LINC02101, AC008786.1, PGAM1P1, PLK2, GAPT, AC008814.1, MIR548AE2, LINC02108, RAB3C, AC016642.1, RPL5P15, AC008852.1, PDE4D, AC092343.1, AC008833.1, NDUFB4P2, MIR582, AC034234.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 9,632 genes in 44 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:33,860,475–46,221,256, 390 genes, copy number 5 (broad region; genes not listed).
- chr1:48,532,854–50,023,954, 1 gene, copy number 5 (within-gene range 2–5): AGBL4.
- chr1:48,926,021–55,215,364, 173 genes, copy number 5 (broad region; genes not listed).
- chr1:55,222,379–55,225,723, 2 genes, copy number 5: GYG1P3, MIR4422.
- chr1:58,785,128–58,901,109, 1 gene, copy number 7 (within-gene range 3–7): LINC01135.
- chr1:58,838,448–71,047,808, 191 genes, copy number 5–7 (within-gene range 2–7) (broad region; genes not listed).
- chr1:143,343,180–183,145,592, 1,272 genes, copy number 5–7 (broad region; genes not listed).
- chr1:207,401,691–245,127,164, 755 genes, copy number 5–7 (broad region; genes not listed).
- chr1:245,154,985–245,709,432, 1 gene, copy number 6 (within-gene range 2–6): KIF26B.
- chr1:245,614,773–248,919,946, 138 genes, copy number 6 (broad region; genes not listed).
- chr4:49,096–35,496,003, 529 genes, copy number 5–8 (broad region; genes not listed).
- chr5:58,198–52,990,278, 744 genes, copy number 5–10 (broad region; genes not listed).
- chr7:726,699–62,275,678, 1,058 genes, copy number 5–7 (broad region; genes not listed).
- chr8:150,584–22,275,162, 498 genes, copy number 5 (broad region; genes not listed).
- chr8:46,028,804–145,066,685, 1,534 genes, copy number 5–6 (broad region; genes not listed).
- chr9:31,505,280–34,774,466, 113 genes, copy number 7 (broad region; genes not listed).
- chr9:38,571,358–43,045,120, 124 genes, copy number 6–11 (within-gene range 4–11) (broad region; genes not listed).
- chr13:52,810,050–53,202,753, 7 genes, copy number 8: MIR759, PPIAP26, PCDH8, OLFM4, LINC01065, AL136359.1, PCDH8P1.
- chr13:60,916,981–64,959,396, 31 genes, copy number 5: LINC01442, MIR3169, PCDH20, AL592490.1, LINC02339, RAC1P8, AL353765.1, LINC00358, LINC01075, LINC01074, LINC00459, RPL32P28, AL356102.1, SQSTM1P1, AL445668.1, LINC00448, AL354810.1, LINC00376, AL359208.1, LINC00395, OR7E156P, AL445989.2, AL445989.1, RNU6-81P, PPP1R2P10, AL445238.2, OR7E104P, AL445238.1, LINC00355, NFYAP1, LGMNP1.
- chr13:66,218,250–91,354,579, 247 genes, copy number 6–23 (broad region; genes not listed).
- chr13:91,485,793–91,996,523, 2 genes, copy number 6: AL356118.1, AL162456.1.
- chr14:27,612,577–51,257,655, 354 genes, copy number 5–7 (broad region; genes not listed).
- chr15:87,859,751–101,933,350, 347 genes, copy number 5–6 (broad region; genes not listed).
- chr18:6,374,361–15,330,282, 250 genes, copy number 6 (broad region; genes not listed).
- chr18:24,426,634–26,391,685, 31 genes, copy number 6 (within-gene range 4–6): IMPACT, Y_RNA, AC007922.2, HRH4, AC007922.1, AC007922.4, AC007922.3, EIF4A3P1, LINC01915, RAC1P1, PPIAP57, AC018697.1, LINC01894, WBP2P1, AC104961.1, ZNF521, AC105114.2, AC105114.1, AC110603.1, RN7SL97P, AC027229.1, SS18, RPS24P18, PSMA8, DHFRP1, NPM1P2, TAF4B, SINHCAFP1, AC121320.1, AC022069.1, RNU6-1289P.
- chr18:28,638,714–28,789,580, 2 genes, copy number 6 (within-gene range 3–6): AC090365.1, ARIH2P1.
- chr18:30,290,161–33,441,101, 61 genes, copy number 6 (within-gene range 3–6) (broad region; genes not listed).
- chr19:10,960,932–12,081,565, 68 genes, copy number 5–8 (within-gene range 2–8) (broad region; genes not listed).
- chr19:15,468,645–15,742,343, 13 genes, copy number 6–14 (within-gene range 2–14): PGLYRP2, CYP4F22, AC011492.1, CYP4F23P, AD000091.1, RPL23AP2, AC093072.1, CYP4F8, CYP4F3, CYP4F10P, CYP4F12, OR10H2, OR10H3.
- chr19:23,492,428–23,958,035, 16 genes, copy number 12: ZNF725P, ZNF675, AC073544.1, RPS27P29, VN1R93P, ZNF681, AC139769.1, BNIP3P39, AC139769.2, RPSAP58, AC139769.3, AC011503.4, ZNF726, AC011503.1, AC011503.2, AC011503.3.
- chr19:27,638,483–30,016,612, 57 genes, copy number 6–28 (within-gene range 3–28): ERVK-28, AC112702.1, LINC00662, AC006504.1, AC006504.5, AC006504.7, AC006504.3, SLC25A1P5, AC006504.2, AC006504.4, AC005357.2, AC006504.6, AC005758.1, AC005357.1, AC010511.1, AC020905.1, AC005580.1, AC093074.1, AC005307.1, AC005394.2, AC005381.1, AC005394.1, AC005616.1, AC079466.2, AC079466.1, AC005524.1, MAN1A2P1, AC007795.1, LINC00906, AC008991.1, AC011524.1, AC011524.2, RNA5SP470, LINC01532, AC011505.1, UQCRFS1, AC007786.1, AC007786.2, AC007786.3, RN7SL340P, AC007786.4, AC011474.1, AC011474.3, AC011474.2, AC011474.4, VSTM2B, POP4, PLEKHF1, C19orf12, AC008798.3, CCNE1, AC008798.2, AC008798.1, AC008507.3, PPIAP58, URI1, RPL9P32.
- chr19:34,677,639–35,169,881, 33 genes, copy number 17 (within-gene range 3–17): ZNF302, AC020910.5, ZNF181, ZNF599, AC020910.3, LINC01801, AC008555.1, AC008555.5, AC008555.2, AC008555.4, AC008555.3, LINC00904, LINC01838, ZNF30-AS1, ZNF30, AC008555.6, ZNF792, GRAMD1A, AC020907.3, AC020907.4, SCN1B, HPN, HPN-AS1, AC020907.1, AC020907.6, FXYD3, MIR6887, LGI4, AC020907.5, FXYD1, AC020907.2, FXYD7, FXYD5.
- chr19:39,731,255–40,090,938, 14 genes, copy number 13 (within-gene range 2–13): CLC, LEUTX, AC005393.1, DYRK1B, MIR6719, FBL, FCGBP, PRR13P5, PSMC4, ZNF546, AC007842.1, ZNF780B, AC005614.2, ZNF780A.
- chr19:42,902,086–42,950,387, 3 genes, copy number 6: PSG6, PSG7, CEACAMP7.
- chr19:43,007,656–43,041,248, 2 genes, copy number 6: PSG11, CEACAMP8.
- chr19:44,259,880–44,401,608, 6 genes, copy number 14 (within-gene range 2–14): ZNF233, AC138473.1, NDUFA3P1, ZNF112, AC245748.1, ZNF285.
- chr19:47,428,017–47,581,321, 8 genes, copy number 16: SLC8A2, AC073548.2, KPTN, NAPA-AS1, NAPA, AC073548.1, ZNF541, RN7SL322P.
- chr19:47,607,873–47,703,277, 4 genes, copy number 16 (within-gene range 2–16): AC010331.1, BICRA, BICRA-AS1, AC008985.1.
- chr19:55,785,397–56,368,383, 19 genes, copy number 15–24 (within-gene range 2–24): NLRP11, NLRP4, NLRP13, NLRP8, NLRP5, LINC01864, ZNF787, Y_RNA, AC024580.2, ZNF444, AC024580.1, GALP, ZSCAN5B, ZSCAN5C, AC011506.1, ZSCAN5A, ZSCAN5DP, EDDM13, AC006116.5.
- chr20:87,250–25,969,288, 529 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 2,031. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
